CCDI case PBCASY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3602211e-2666-48ae-857b-b3bc66d261b2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 5.7 years (2,078 days).

Biospecimens (3 samples)
- Sample 0DMN1E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN27: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
